Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A8HO, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A8HO-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

PROSTATE, RESECTION
RIGHT PELVIC NODES
LEFT PELVIC NODES

ICD O-3
Adenocarcinoma, acinar
8/40/13
Site: Prostate NGS
C61.9
JW 11/29/13

GROSS DESCRIPTION

Specimen is received fresh in one container labeled with patient's name and "prostate + seminal vesicles". The specimen consists of a radical prostatectomy weighing 94.42 grams. The prostate measures 6.0 cm. x 5.0 cm x 4.5 cm. The left vas deferens measures 3.0 cm. x 0.5 cm. The anterior aspect of the prostate is inked red, and the posterior aspect is inked black. Specimen is sectioned as per protocol and submitted as per summary of sections. Please note that some tissue is tissue banked.

**SUMMARY OF SECTIONS**

A1 = LEFT VAS DEFERENS;
A2 = BLADDER NECK, SHAVE D MARGIN;
A3 = RIGHT ANTERIOR APEX;
A4-A8 = RIGHT ANTERIOR QUADRANT, APEX TO BASE;
A9 = RIGHT ANTERIOR MARGINS;
A10 = RIGHT ANTERIOR BASE;
A11 = RIGHT ANTERIOR BASE
A12 = RIGHT POSTERIOR APEX;
A13-A15 = RIGHT POSTERIOR QUADRANT, APEX TO BASE;
A16 = RIGHT POSTERIOR MARGINS;
A17 = RIGHT POSTERIOR BASE;
A18 = LEFT ANTERIOR APEX;
A19 AND A20 = LEFT ANTERIOR QUADRANT, APEX TO BASE;
A21 = LEFT ANTERIOR MARGINS;
A22 = LEFT ANTERIOR BASE;
A23 = LEFT ANTERIOR BASE;
A24 = LEFT POSTERIOR APEX;
A25-A27 = LEFT POSTERIOR QUADRANT, APEX TO BASE;
A28 = LEFT POSTERIOR MARGINS;
A29 = LEFT POSTERIOR BASE;
A30 = LEFT POSTERIOR BASE.

DIAGNOSIS

PROSTATE GLAND, RADICAL PROSTATECTOMY WITH RIGHT AND LEFT PELVIC LYMPHADENECTOMY:

PRIMARY TUMOR DIAGNOSIS :

- ADENOCARCINOMA (ACINAR, NOT OTHERWISE SPECIFIED).

GLEASON SCORE: 4 + 3 = 7 / 10. WITH A TERTIARY COMPONENT 5.

LOCATION OF TUMOR :

- TUMOR INVOLVES BOTH LOBES, (RIGHT ANTERIOR, RIGHT POSTERIOR, LEFT ANTERIOR LEFT POSTERIOR QUADRANTS).

EXTENT OF TUMOR :

- TUMOR DEMONSTRATES EXTRA-PROSTATIC EXTENSION, UNILATERAL (LEFT SIDE).
- TUMOR DOES NOT INVADE THE MUSCULAR WALL OF THE SEMINAL VESICLE.

MARGIN OF EXCISION :

- TUMOR IS PRESENT AT THE BLADDER BASE MARGIN.

[page 2 of 2]
LYMPH NODES, RIGHT PELVIC :

- 8 BENIGN LYMPH NODES (0/8).

LYMPH NODES, LEFT PELVIC :

- 10 BENIGN LYMPH NODES (0/10).

ADDITIONAL TUMOR FEATURES :

- TUMOR INVOLVES APPROXIMATELY 15 TO 20% OF THE PROSTATE GLAND.
- VASCULAR INVASION IS NOT IDENTIFIED.
- PERINEURAL INVASION IS IDENTIFIED.
- EXTENT OF EXTRA-PROSTATIC SPREAD : FOCAL.
- EXTENT OF MARGIN POSITIVITY : FOCAL.

ADDITIONAL FINDINGS AND COMMENTS :

- PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.
- BASAL CELL HYPERPLASIA.
- ATROPHY.

TNM : pT3a (R1: residual microscopic disease), N0, Mx.

Item	Yes	No
Diagnostic Discrepancy		✓
Primary Turnout Site Discrepancy		✓
IP: A Discrepancy		✓
Field Malfunction History		✓
Not "Over-the-horizon" or "Out of Range"		✓
Inspector Initials	Date Reviewed	11/5/13

Source: NCI Genomic Data Commons file cd385d0b-2b4d-40c2-afc5-d8e8d3ab793c (TCGA-YL-A8HO.3C690B20-F9EC-456D-B397-928E39B3FFE2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).